Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A6TE, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A6TE-01A (Primary Tumor).

[page 1 of 6]
Sample #

Gender: Male

DOB:

Race: White

Report Date:

Pathology Report:

ICD-0-3
Carcinoma, urothelial NOS
Site 06CF 8/20/13
Inguin of bladder
path C67.0
Lateral wall of bladder
C67.2
JW 8/7/13

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

A. Left distal ureter; excision:

- Ureter margin, free of tumor.
- Urothelial carcinoma in situ present at non-margin side.

B. Urinary bladder and prostate; cystoprostatecomy:

- Bladder with high grade urothelial carcinoma invading thru the muscularis propria and into the perivesical fat, see pathologic parameters.
- Prostate with incidental prostatic adenocarcinoma, see pathologic parameters.

C. Left pelvic lymph node; dissection:

- One of nine lymph nodes, positive for metastatic urothelial carcinoma (1/9).
- Lymph nodal tumor measures 2.7 cm, with extranodal tumor extension.

D. Right pelvic lymph node; dissection:

- One of thirteen lymph nodes, positive for metastatic urothelial carcinoma (1/13).

E. Right common iliac lymph node; dissection:

- Five lymph nodes, no tumor (0/5)

F. Left common iliac lymph node; dissection:

- Seven lymph nodes, no tumor (0/7)

G. Pre sacral lymph nodes; dissection:

- Four lymph nodes, no tumor (0/4)

H. Meckel's; excision:

- Meckel diverticulum

I. Vas deferens, bilateral; excision:

[page 2 of 6]
- Bilateral vasa deferentia, no tumor

J. Right distal ureter; excision:

- Portion of ureter, no tumor

Urothelial Carcinoma Pathologic Parameters

1. Tumor type: Invasive conventional urothelial carcinoma.
2. Grade of tumor: High grade.
3. Depth of invasion: Extravesicular soft tissue (microscopic).
4. Tumor distribution: Solitary, left lateral wall and trigone, 3.0 cm.
5. Ureteral margins: Negative for tumor.
6. Distal urethral margin: Negative for tumor.
7. Soft tissue margin or serosa: Negative for tumor.
8. Lymph nodes: Positive for metastatic urothelial carcinoma (2/38).
9. pTNM: pT3a,N2,MX.

Effective January 1, 2010 this Checklist utilizes the 7th edition TNM staging system for Bladder of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

Radical Prostatectomy Pathologic Parameters

1. Gleason Score: 3+3=6.
2. Perineural Invasion: Absent.
3. Tumor Location: Peripheral zone right and left.
4. Tumor Volume Estimate: <3%
5. High-grade P.I.N.: Multifocal.
6. Seminal Vesicles: Negative for tumor.
7. Extraprostatic extension: Absent.
8. Peripheral Margin: Negative for tumor.
9. Distal (apical) Margin: Negative for tumor.
10. Proximal (basilar) Margin: Negative for tumor
11. Regional Lymph Nodes (right and left): Negative for prostatic carcinoma (0/38).
12. pTNM: pT2a,N0,MX.

Effective January 1, 2010 this Checklist utilizes the 7th edition TNM staging system for prostatectomy of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, [], MD

[page 3 of 6]
Electronically Signed Out by [], MD

Clinical History:

Patient is a year-old male clinical history of bladder cancer who undergoes cystoprostatectomy.

Specimens Received:

- A: Left distal ureter
- B: Bladder, prostate-stat for prostate urethral margin
- C: Left pelvic lymph node
- D: Right pelvic lymph node
- E: Right common iliac lymph node
- F: Left common iliac lymph node
- G: Pre sacral lymph nodes
- H: Mekel's (sp)
- I: Vas deferens, bilateral
- J: Right distal ureter

Gross Description:

The specimens are received in ten containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "left distal ureter-stitch on non-margin side". Received fresh for intraoperative consultation is a 1.0 cm in length by 0.5 cm in external diameter rubbery, tan-pink and tubular portion of ureter with attached adipose tissue measuring up to 1 cm in thickness. The margin is inked blue and frozen and diagnosed as "segment of ureter, no tumor present" per Dr. [] The frozen section diagnosis is reported to by Dr. [] at on The frozen section remnant is entirely submitted in cassette A1 FS. The non-margin aspect of the ureter submitted in cassette A2.

B. The second container is additionally identified as, "bladder, prostate-stat for prostate urethral margin". Received fresh for intraoperative consultation and placed in formalin is a 204 g (following-fixation), 14 x 7.5 x 5.2 cm cystoprostatectomy specimen consisting of a 6 x 5.5 x 5 cm bladder with attached mesenteric fat and a 3.8 x 2.0 x 2.4 cm prostate. The right seminal vesicles measures 2.1 x 1.7 x 0.7 cm and right vas deferens measures 2 x 0.6 cm. The left seminal vesicles measures 1.5 x 1.1 x 0.6 cm and left vas deferens is not present. The right ureteral stump measures 0.6 x 0.4 cm, the left measures 0.2 (length) x 0.4 cm, and both demonstrate intact, patent lumens.

The prostate urethral margin is frozen and diagnosed as "no tumor" per Dr. [] The frozen section diagnoses reported to Dr. [] by Dr. [] at

[page 4 of 6]
The right half of the prostate and bladder is inked blue and the left half is inked black. The bladder and prostate are opened anteriorly along the urethra. The prostate is surrounded by a thin, intact membranous capsule and sectioning demonstrates rubbery, pink-tan, peri-urethral nodularity with no discrete masses or induration.

The opened bladder reveals a 3 x 2.8 cm raised, firm, pink-tan lesion mass located in left lateral wall. On cut section, the mass extends into but not through the muscularis mucosa and is 1.7 cm from the deep margin. The surrounding bladder mucosa is edematous, wrinkled and gray-tan with a uniform 1.1-1.2 cm wall thickness. Bilateral ureteral orifices, adjacent to the trigone, are identified and probe patent.

Representative sections are submitted as follows:

- B1: Distal prostatic urethral margin
- B2: Right ureter resection margin
- B3: Left ureter resection margin
- B4: Prostate apex serially sectioned
- B5-B12: Bladder mass/Ulceration
- B13: Uninvolved bladder mucosa bladder dome
- B14: Uninvolved bladder mucosa anterior wall
- B15: Uninvolved bladder mucosa posterior wall
- B16: Uninvolved bladder mucosa left lateral wall
- B17: Uninvolved bladder mucosa right lateral wall
- B18: Uninvolved bladder mucosa trigone
- B19: Left and right seminal vesicles
- B20-24: Representative right and left lobes of prostate from apex to base

C. The third container is additionally identified as, "left pelvic lymph node". Received fresh and placed in formalin is a 7.1 x 5.3 cm aggregate of soft to rubbery, yellow-tan and lobulated fibroadipose tissue which is dissected to reveal 13 lymph node candidates measuring up to 2.7 cm in greatest dimension. The lymph node candidates are submitted as follows:

- C1: 7 lymph node candidates
- C2: 3 lymph node candidates
- C3: 1 lymph node candidate
- C4: 1 lymph node candidate
- C5-C7: 1 lymph node candidate sectioned

D. The fourth container is additionally identified as, "right pelvic lymph node". Received fresh and placed in formalin is a 5.4 x 3.4 x 1.2 cm aggregate of soft, yellow-tan and lobulated fibroadipose tissue which is dissected to reveal 7 lymph node candidates measuring up to 2.1 cm in greatest dimension. The specimen is entirely submitted as follows:

[page 5 of 6]
D1: 5 lymph node candidates
D2: 1 lymph node candidate bisected
D3: One lymph node candidate bisected
D4-D6: Fibroadipose tissue entirely submitted
D7: One lymph node candidate sectioned

E. The fifth container is additionally identified as, "right common iliac lymph node". Received fresh and placed in formalin are 5 rubbery, ovoid and gray-tan tissue fragments ranging in size from 0.8 to 1.7 cm in greatest dimension. The specimen is entirely submitted as follows:

E1: One lymph node candidate
E2: 3 lymph node candidates
E3: One lymph node candidate

F. The sixth container is additionally identified as, "left common iliac lymph node". Received fresh and placed in formalin are 5 firm, gray-brown and irregular tissue fragments ranging in size from 0.4-8.0 cm in greatest dimension. The specimen is entirely submitted as follows:

F1: Four lymph node candidates
F2-F4: 8 cm segment of fibroadipose tissue, sectioned

G. The seventh container is additionally identified as, "presacral lymph nodes". Received fresh and placed in formalin is a single 7.1 cm in length by 1.7 cm in diameter tubular segment of fibroadipose tissue which is dissected to reveal 5 lymph node candidates measuring up to 0.5 cm in greatest dimension. The specimen is entirely submitted as follows:

G1-G5: One lymph node candidate in each cassette

H. The eighth container is additionally identified as, "Meckel's". Received fresh and placed in formalin is a 2 cm in length by 1.1 cm in diameter tubular portion of bowel with attached adipose tissue measuring up to 0.4 cm in diameter. At one aspect of the specimen there is a patent tubular segment. The specimen is trisected to reveal a cystic space filled with white-tan friable tissue fragments and apparent bowel mucosa. The specimen is entirely submitted in cassette H1.

I. The ninth container is additionally identified as, "vas deferens bilateral". Received fresh and placed in formalin are two unoriented and undesignated segments of vas deferens which measure 3.4 x 0.3 (arbitrarily designated A) and 4.1 x 0.2 cm arbitrarily designated B). Vas deferens A is inked blue and vas deferens B is inked black and they are representatively submitted in cassette I1.

J. The tenth container is additionally identified as, "right distal ureter, stitch on margin side". Received fresh and placed in formalin is a 3.1 cm in length by 0.4 cm in diameter segment of ureter with attached adipose tissue

[page 6 of 6]
measuring up to 0.3 cm in thickness. The specimen is oriented with a stitch at the non-margin aspect. The non-margin aspect is inked blue, the margin aspect is inked black. The non-margin aspect, the margin aspect and a representative central portion are submitted in cassette J1.

Intraoperative Consult Diagnosis:

A1 FS (ureter): Segment of ureter no tumor present

Source: NCI Genomic Data Commons file afbec341-4c40-402d-8b26-57814cca0cd5 (TCGA-FD-A6TE.648DDD7D-6C27-4CA1-BBB2-891A9F7839FE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).